CCDI case PBCCTE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d65476e3-7c77-4b6e-9e24-2bff39bf440f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Atypical meningioma: ICD-O-3 morphology code: 9539/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.0 years (1,830 days).

Biospecimens (3 samples)
- Sample 0DOTA7: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DOTAV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DPCYD: Tissue type: Tumor; Specimen type: Solid Tissue.
